FM case AD11757 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/b399543a-3cd1-4999-9ffe-7454ec6dea21

Female, 47.7 years: Papillary serous adenocarcinoma (ICD-O-3 8460/3) of the uterus; primary biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
